Somatic mutation profile of tumor specimen BA2212D (aliquot aq-BA2212D) from BEATAML1.0 case 2035, project BEATAML1.0-COHORT (Functional Genomic Landscape of Acute Myeloid Leukemia). Sex at birth: male; Vital status: Dead; Primary diagnosis: Acute myeloid leukemia with myelodysplasia-related changes; Tissue or organ of origin: Bone marrow; Age at diagnosis: 75.4 years (27,543 days).
Specimen BA2212D: Sample type: Recurrent Blood Derived Cancer - Bone Marrow; Tissue type: Tumor; Tumor descriptor: Recurrence; Specimen type: Bone Marrow NOS; Preservation method: Snap Frozen.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) 589b7952-2fe2-4b41-9f86-6dbebab774f6.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen BA2890D (Solid Tissue Normal), aliquot aq-BA2890D; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/153324bb-04bf-48b8-af50-a78f8a7034c6

The open-access MAF lists 14 somatic variants for this specimen: 12 protein-altering or splice-affecting, 1 silent, 1 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 10, Frame Shift Del 1, Intron 1, Silent 1, Nonsense Mutation 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- EPS8L1 | c.1187C>A p.S396* (on ENST00000201647 / NM_133180.3; = p.S269* on NM_017729.3) | Nonsense Mutation (SNP) | VAF 4/71 reads (6%) | catalogued as COSV99135902; called by muse, mutect2
- FASTKD5 | c.1102G>A p.V368M | Missense Mutation (SNP) | VAF 46/394 reads (12%) | SIFT tolerated (0.33); PolyPhen possibly damaging (0.452); catalogued as rs149209962; called by muse, mutect2, varscan2
- KIF2B | c.98C>T p.A33V | Missense Mutation (SNP) | VAF 9/200 reads (5%) | SIFT tolerated (0.16); PolyPhen benign (0.184); catalogued as COSV52126814; called by muse, mutect2
- SLITRK6 | c.448G>A p.V150M | Missense Mutation (SNP) | VAF 45/206 reads (22%) | SIFT tolerated (0.22); PolyPhen possibly damaging (0.795); catalogued as COSV68390388; called by muse, mutect2, varscan2
- TET2 | c.3813del p.C1271Wfs*92 | Frame Shift Del (DEL) | VAF 8/81 reads (10%) | catalogued as COSV54395761, COSV54418100, COSV54426906, COSV99480757; called by mutect2, pindel
- VIP | c.407G>A p.R136H | Missense Mutation (SNP) | VAF 20/147 reads (14%) | SIFT deleterious (0.04); PolyPhen probably damaging (0.971); catalogued as rs778821449, COSV65889066; called by muse, mutect2
- EFHB | c.770G>T p.R257L | Missense Mutation (SNP) | VAF 3/37 reads (8%) | SIFT deleterious (0); PolyPhen probably damaging (0.956); called by muse, mutect2
- GUCY2F | c.1340G>T p.R447I | Missense Mutation (SNP) | VAF 3/28 reads (11%) | SIFT tolerated (0.18); PolyPhen benign (0.01); called by muse, mutect2
- IFNA5 | c.59G>T p.C20F | Missense Mutation (SNP) | VAF 4/50 reads (8%) | SIFT tolerated (0.23); PolyPhen benign (0.114); called by muse, mutect2
- SLC13A3 | c.1220C>A p.A407D | Missense Mutation (SNP) | VAF 11/30 reads (37%) | SIFT tolerated (0.16); PolyPhen possibly damaging (0.843); called by muse, mutect2, varscan2
- ST6GALNAC6 | c.512T>G p.F171C | Missense Mutation (SNP) | VAF 8/21 reads (38%) | PolyPhen probably damaging (1); called by muse, mutect2, varscan2
- UGCG | c.577C>A p.H193N | Missense Mutation (SNP) | VAF 3/49 reads (6%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.991); called by muse, mutect2
- SAFB | c.2199T>C p.D733= | Silent (SNP) | VAF 49/116 reads (42%) | called by muse, mutect2, varscan2
- NDUFS8 | c.-1+217A>G | Intron (SNP) | VAF 19/38 reads (50%) | called by muse, mutect2, varscan2
